CCDI case PBCDIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/e61f18b8-d4f7-483d-8f7f-229b38afccb5

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 11.0 years (4,032 days).

Biospecimens (3 samples)
- Sample 0DP6HN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DP6HY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DP6ID: Tissue type: Tumor; Specimen type: Solid Tissue.
